Somatic mutation profile of tumor specimen MMRF_2493_1_BM_CD138pos (aliquot MMRF_2493_1_BM_CD138pos_T1_KHS5U_K15171) from MMRF case MMRF_2493, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.0 years (25,184 days).
Specimen MMRF_2493_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b68efa29-e518-4cc9-afe4-07c0bc2eb112.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2493_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2493_1_PB_Whole_C2_KHS5U_K15170; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/780e36e4-fcf4-476e-8937-b960d6461b15

The open-access MAF lists 141 somatic variants for this specimen: 59 protein-altering or splice-affecting, 16 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, 3'UTR 37, Silent 16, Intron 15, 5'Flank 5, RNA 4, 5'UTR 4, Nonsense Mutation 3, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1436A>G p.D479G | Missense Mutation (SNP) | VAF 99/236 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705800, COSV66705888; called by muse, mutect2, varscan2
- TP53 | c.707A>C p.Y236S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: uncertain significance; called by muse, mutect2
- ABCC3 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.168); catalogued as rs755878262, COSV53324387, COSV99559045; called by muse, mutect2
- ADAM29 | c.2078G>T p.C693F | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV63668343; called by muse, mutect2, varscan2
- CCKAR | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1361719100; called by muse, mutect2
- CLSTN2 | c.1961G>A p.R654K | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs770215430; called by muse, mutect2, varscan2
- COL21A1 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs959481391, COSV55184484; called by muse, mutect2, varscan2
- CRISP3 | c.691G>A p.D231N (on ENST00000371159 / NM_001368123.1; = p.D213N on NM_006061.4) | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs996891773, COSV53819037; called by muse, mutect2, varscan2
- CTNNA3 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs769809500, COSV65549469; called by muse, mutect2, varscan2
- IGLV4-60 | c.229T>C p.Y77H | Missense Mutation (SNP) | VAF 117/271 reads (43%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs377230235; called by muse, mutect2
- IGLV4-60 | c.231C>G p.Y77* | Nonsense Mutation (SNP) | VAF 114/270 reads (42%) | catalogued as rs567096325, COSV66503515; called by muse, mutect2
- MMP17 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 32/383 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs143699569; called by muse, mutect2
- MRGPRG | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.366); catalogued as rs1466343580; called by muse, mutect2, varscan2
- OBSL1 | c.3961G>A p.G1321R | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192049617; called by muse, mutect2, varscan2
- PCDHA5 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.87); catalogued as rs868924111, COSV65349820; called by muse, mutect2, varscan2
- PRB3 | c.135C>G p.N45K | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs1339530763, COSV54391724; called by muse, mutect2
- RAD51AP2 | c.1787G>T p.R596I | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV67587770; called by muse, mutect2, varscan2
- RNASEL | c.541G>C p.V181L | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs779087511; called by muse, mutect2, varscan2
- ROBO3 | c.4141C>T p.R1381C | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1033501473; called by muse, mutect2, varscan2
- SEL1L3 | c.902A>C p.K301T | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV53543017; called by muse, mutect2, varscan2
- SP140 | c.2535A>T p.R845S | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs750294624; called by muse, mutect2, varscan2
- TCL1A | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 246/271 reads (91%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201228671, COSV68085105, COSV68085114, COSV68085683; called by muse, mutect2, varscan2
- THSD7A | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs754991357; called by muse, mutect2, varscan2
- TSPOAP1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52105983; called by muse, mutect2, varscan2
- UNC13C | c.3475G>T p.G1159C | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV52854602; called by muse, mutect2
- ZMYND12 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.075); catalogued as COSV65341746; called by muse, mutect2
- ZNF626 | c.346G>T p.G116* | Nonsense Mutation (SNP) | VAF 18/184 reads (10%) | catalogued as rs782322875, COSV74129001; called by muse, mutect2
- ZNF841 | c.994C>A p.Q332K (on ENST00000426391 / NM_001369830.1; = p.Q448K on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.176); catalogued as rs1246445462; called by muse, mutect2, varscan2
- ZNF98 | c.344G>A p.C115Y | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs750517730; called by muse, mutect2, varscan2
- C4orf54 | c.4300G>A p.G1434R | Missense Mutation (SNP) | VAF 105/207 reads (51%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLTC | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2
- COLEC12 | c.866A>C p.Q289P | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DEPTOR | c.792G>A p.V264= | Splice Region (SNP) | VAF 61/122 reads (50%) | called by muse, mutect2, varscan2
- DNAJB7 | c.711C>G p.C237W | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.137); called by muse, mutect2
- EMC2 | c.241A>G p.R81G | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EXOC8 | c.750G>A p.M250I | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- FAM120C | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.736); called by muse, varscan2
- FREM1 | c.3879T>G p.I1293M | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- GALT | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- IGLV6-57 | c.64A>C p.M22L | Missense Mutation (SNP) | VAF 136/284 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, varscan2
- LRRIQ1 | c.4946A>T p.N1649I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MAK | c.1090C>A p.Q364K | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MNS1 | c.1464G>T p.R488S | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- MPDZ | c.3201T>A p.N1067K | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- MYO18B | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- MYRFL | c.2716T>C p.Y906H | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- NRXN3 | c.1004T>G p.I335S | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR5W2 | c.267C>A p.N89K | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB16 | c.838A>C p.T280P | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- RANBP6 | c.1525A>T p.I509F | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SLC44A5 | c.880A>C p.T294P | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TECRL | c.650T>A p.L217* | Nonsense Mutation (SNP) | VAF 49/109 reads (45%) | called by muse, mutect2, varscan2
- TMC1 | c.1889C>A p.S630Y | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRRAP | c.8039C>G p.S2680C (on ENST00000359863 / NM_001244580.1; = p.S2662C on NM_003496.3) | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTN | c.50171G>A p.G16724E (on ENST00000591111; = p.G9300E on NM_003319.4) | Missense Mutation (SNP) | VAF 75/260 reads (29%) | PolyPhen benign (0.344); called by muse, mutect2, varscan2
- USP19 | c.1600A>G p.I534V | Missense Mutation (SNP) | VAF 147/307 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF2 | c.745A>G p.K249E (on ENST00000611147 / NM_001291605.2; = p.K236E on NM_021088.4) | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF454 | c.982T>A p.Y328N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF471 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.031); called by muse, mutect2
- ADAMTS1 | c.2439C>T p.S813= | Silent (SNP) | VAF 61/150 reads (41%) | catalogued as COSV53170656, COSV53173616; called by muse, mutect2, varscan2
- FASN | c.5301G>A p.L1767= | Silent (SNP) | VAF 32/360 reads (9%) | called by muse, mutect2
- FKBP3 | c.540G>A p.L180= | Silent (SNP) | VAF 78/280 reads (28%) | called by muse, mutect2, varscan2
- IL6ST | c.234A>G p.Q78= | Silent (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- ILDR2 | c.492G>A p.L164= | Silent (SNP) | VAF 11/218 reads (5%) | called by muse, mutect2
- NKD2 | c.297G>A p.P99= | Silent (SNP) | VAF 72/162 reads (44%) | catalogued as rs1339715695, COSV104386106; called by muse, mutect2, varscan2
- NOTCH3 | c.4428C>T p.A1476= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as rs971777724; called by muse, mutect2, varscan2
- PCDHB6 | c.651G>T p.G217= | Silent (SNP) | VAF 31/225 reads (14%) | catalogued as rs375636490; called by muse, mutect2, varscan2
- PROKR1 | c.723C>T p.F241= | Silent (SNP) | VAF 210/415 reads (51%) | catalogued as rs146411193; called by muse, mutect2, varscan2
- SPATA13 | c.1812G>A p.P604= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as rs750379282, COSV57976181; called by muse, mutect2
- SPATA18 | c.219A>T p.T73= | Silent (SNP) | VAF 66/151 reads (44%) | called by muse, mutect2, varscan2
- STAM | c.1485C>T p.V495= | Silent (SNP) | VAF 37/193 reads (19%) | catalogued as rs1554830564; called by muse, mutect2, varscan2
- TMEM229A | c.219G>A p.S73= | Silent (SNP) | VAF 47/176 reads (27%) | called by muse, mutect2, varscan2
- UNC79 | c.4089G>T p.V1363= (on ENST00000393151 / NM_001346218.2; = p.V1186= on NM_020818.5) | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as COSV99829308; called by muse, mutect2
- ZNF197 | c.1059C>T p.F353= | Silent (SNP) | VAF 30/299 reads (10%) | catalogued as rs202099639; called by muse, mutect2
- ZNF324B | c.552G>A p.V184= | Silent (SNP) | VAF 61/229 reads (27%) | catalogued as COSV60743259; called by muse, mutect2, varscan2
- AADACL3 | c.*1684C>A | 3'UTR (SNP) | VAF 84/188 reads (45%) | called by muse, mutect2, varscan2
- AC090155.1 | n.165G>C | RNA (SNP) | VAF 6/28 reads (21%) | catalogued as rs1457802372; called by muse, mutect2
- AC093802.1 | n.1914+7076G>T | Intron (SNP) | VAF 127/478 reads (27%) | called by muse, mutect2, varscan2
- AC136759.1 | n.491C>T | RNA (SNP) | VAF 66/414 reads (16%) | called by muse, mutect2, varscan2
- ACTG1 | c.-70G>C | 5'UTR (SNP) | VAF 114/236 reads (48%) | called by muse, mutect2, varscan2
- ADCY7 | c.*1881C>G | 3'UTR (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- ADGRA1 | c.*396G>A | 3'UTR (SNP) | VAF 26/153 reads (17%) | called by muse, mutect2, varscan2
- AHR | c.*1316C>A | 3'UTR (SNP) | VAF 58/141 reads (41%) | called by muse, mutect2, varscan2
- ARAP2 | c.*684A>G | 3'UTR (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- BMP2KL | n.528A>G | RNA (SNP) | VAF 53/61 reads (87%) | called by muse, mutect2, varscan2
- CALHM5 | c.*1031G>C | 3'UTR (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- CAMK4 | c.*2495C>A | 3'UTR (SNP) | VAF 11/81 reads (14%) | catalogued as rs1395452012; called by muse, mutect2, varscan2
- CCNDBP1 | c.-40A>T | 5'UTR (SNP) | VAF 31/86 reads (36%) | called by muse, mutect2, varscan2
- CD1D | c.607+80T>C | Intron (SNP) | VAF 41/133 reads (31%) | called by muse, mutect2, varscan2
- CD36 | c.*67C>T | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- CDC37P2 | n.923C>T | RNA (SNP) | VAF 35/115 reads (30%) | catalogued as rs1329618294; called by muse, mutect2, varscan2
- COL15A1 | chr9:98943689 A>T | 5'Flank (SNP) | VAF 40/128 reads (31%) | called by muse, mutect2, varscan2
- CORO1C | c.-5-1562G>T | Intron (SNP) | VAF 193/424 reads (46%) | called by muse, mutect2, varscan2
- CRIM1 | c.*2050T>A | 3'UTR (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- CRX | c.*1110T>G | 3'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- CSRP3 | c.*27dup | 3'UTR (INS) | VAF 156/609 reads (26%) | catalogued as rs534055346; called by mutect2, pindel, varscan2
- DDX19A | c.386+40A>T | Intron (SNP) | VAF 80/144 reads (56%) | called by muse, mutect2, varscan2
- DIO3 | chr14:101558010 C>A | 5'Flank (SNP) | VAF 171/190 reads (90%) | called by muse, mutect2, varscan2
- DISC1 | c.*399T>C | 3'UTR (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- DMD | c.*951A>C | 3'UTR (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
- ELOVL2 | c.*912dup | 3'UTR (INS) | VAF 30/113 reads (27%) | called by mutect2, pindel, varscan2
- ENAM | c.*340G>A | 3'UTR (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- EPN2 | c.*1555A>G | 3'UTR (SNP) | VAF 21/232 reads (9%) | called by muse, mutect2
- FAM227B | c.546+521C>T | Intron (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2
- FBXW8 | chr12:117031091 A>G | 3'Flank (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- FOXI2 | c.*1870G>A | 3'UTR (SNP) | VAF 31/59 reads (53%) | called by muse, varscan2
- GABRA5 | c.*304T>G | 3'UTR (SNP) | VAF 45/125 reads (36%) | called by muse, mutect2, varscan2
- GABRG2 | c.*1280C>G | 3'UTR (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- GLIS2 | c.*1672T>A | 3'UTR (SNP) | VAF 54/175 reads (31%) | called by muse, mutect2, varscan2
- HOXC6 | c.*15G>A | 3'UTR (SNP) | VAF 203/420 reads (48%) | called by muse, mutect2, varscan2
- HS3ST1 | c.*2695G>C | 3'UTR (SNP) | VAF 61/132 reads (46%) | called by muse, mutect2, varscan2
- KIAA1143 | c.*2758G>A | 3'UTR (SNP) | VAF 26/196 reads (13%) | called by muse, mutect2, varscan2
- NAALAD2 | c.*236del | 3'UTR (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- NRXN1 | c.3365-110358C>A | Intron (SNP) | VAF 134/300 reads (45%) | called by muse, mutect2, varscan2
- PCDH10 | c.*309T>G | 3'UTR (SNP) | VAF 45/107 reads (42%) | called by muse, mutect2, varscan2
- PDE4D | c.*106G>A | 3'UTR (SNP) | VAF 14/274 reads (5%) | called by muse, mutect2
- PDIA3 | c.-49C>T | 5'UTR (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- PDZRN3 | chr3:73625046 C>A | 5'Flank (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- PIP4P2 | c.*153A>C | 3'UTR (SNP) | VAF 65/137 reads (47%) | called by muse, mutect2, varscan2
- PIWIL1 | c.*415A>T | 3'UTR (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- PLA2G4D | c.2043+16C>A | Intron (SNP) | VAF 84/175 reads (48%) | called by muse, mutect2, varscan2
- PRKRA | c.235+101G>A | Intron (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- PSD3 | c.2086+40T>G | Intron (SNP) | VAF 108/239 reads (45%) | called by muse, mutect2, varscan2
- RIN3 | c.*253A>G | 3'UTR (SNP) | VAF 16/340 reads (5%) | called by muse, mutect2
- SCN3B | c.*136T>A | 3'UTR (SNP) | VAF 33/313 reads (11%) | called by muse, mutect2, varscan2
- SEL1L | c.*3341G>A | 3'UTR (SNP) | VAF 24/77 reads (31%) | catalogued as rs866928426; called by muse, mutect2, varscan2
- SIAH3 | c.*557G>T | 3'UTR (SNP) | VAF 90/197 reads (46%) | called by muse, mutect2, varscan2
- SLC3A2 | chr11:62853614 G>C | 5'Flank (SNP) | VAF 60/143 reads (42%) | called by muse, mutect2, varscan2
- SLCO4A1 | c.1472+15G>A | Intron (SNP) | VAF 12/108 reads (11%) | catalogued as rs1354799581; called by muse, mutect2
- SOX11 | c.*5275T>C | 3'UTR (SNP) | VAF 59/121 reads (49%) | called by muse, mutect2, varscan2
- SPCS3 | c.144-98dup | Intron (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel
- SPOCK2 | c.*466A>G | 3'UTR (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- ST8SIA6 | c.*245A>T | 3'UTR (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- STAG3 | c.2220+48T>C | Intron (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- THEM4 | chr1:151909588 C>G | 5'Flank (SNP) | VAF 35/87 reads (40%) | catalogued as rs1298114011; called by muse, mutect2, varscan2
- TMPO | c.*494A>G | 3'UTR (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- TNNI3K | c.1879-44C>A | Intron (SNP) | VAF 23/55 reads (42%) | catalogued as rs965021075; called by muse, mutect2, varscan2
- TTC39B | c.*386T>A | 3'UTR (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- VTI1A | c.560+67824A>G | Intron (SNP) | VAF 158/405 reads (39%) | catalogued as rs1255269814; called by muse, mutect2, varscan2
- ZCCHC12 | c.-49A>G | 5'UTR (SNP) | VAF 94/143 reads (66%) | called by muse, mutect2, varscan2
- ZNF415 | c.136+593C>T | Intron (SNP) | VAF 40/129 reads (31%) | called by muse, mutect2, varscan2
